Somatic mutation profile of tumor specimen C3L-08269-01 (aliquot CPT0477820006) from CPTAC case C3L-08269, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: GX; Age at diagnosis: 75.7 years (27,632 days).
Specimen C3L-08269-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d3335b32-4ac9-4dc0-9732-f0a9c63c0c8c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-08269-31 (Blood Derived Normal), aliquot CPT0475720003; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/03c403bc-58cd-4dc8-8aec-3eb9bfe16be5

The open-access MAF lists 142 somatic variants for this specimen: 103 protein-altering or splice-affecting, 33 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 89, Silent 33, Nonsense Mutation 10, Intron 5, 3'Flank 1, Translation Start Site 1, Frame Shift Del 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RHOA | c.185G>A p.G62E | Missense Mutation (SNP) | VAF 36/331 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69041792, COSV69042056; called by muse, mutect2
- ABCA1 | c.3821C>A p.A1274D | Missense Mutation (SNP) | VAF 38/420 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs755797391; called by muse, mutect2
- ABO | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 45/420 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.347); catalogued as rs782075362; called by muse, mutect2
- ACSM5 | c.1012C>T p.Q338* | Nonsense Mutation (SNP) | VAF 32/219 reads (15%) | catalogued as rs753842704; called by muse, mutect2, varscan2
- ADAMTS7 | c.2456C>T p.P819L | Missense Mutation (SNP) | VAF 34/452 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs143462516, COSV101183007; called by muse, mutect2
- C19orf67 | c.856G>A p.G286S | Missense Mutation (SNP) | VAF 46/411 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs142790837; called by muse, mutect2, varscan2
- C1QTNF7 | c.131G>A p.G44E | Missense Mutation (SNP) | VAF 36/338 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766635266; called by muse, mutect2, varscan2
- CACNA1E | c.4781G>A p.R1594H | Missense Mutation (SNP) | VAF 28/366 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1436277931, COSV62382452; called by muse, mutect2
- CBFA2T3 | c.1073G>A p.R358H | Missense Mutation (SNP) | VAF 28/372 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.985); catalogued as rs760610315, COSV51925320; called by muse, mutect2
- CCDC168 | c.10307G>A p.R3436Q | Missense Mutation (SNP) | VAF 32/388 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.251); catalogued as rs780030415; called by muse, mutect2
- CDH9 | c.428C>T p.S143L | Missense Mutation (SNP) | VAF 28/452 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs558544451, COSV50254945, COSV50256906; called by muse, mutect2
- CEACAM5 | c.730C>T p.P244S | Missense Mutation (SNP) | VAF 18/249 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs1412930045; called by muse, mutect2
- CHD6 | c.6859C>T p.R2287W | Missense Mutation (SNP) | VAF 50/566 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750678347; called by muse, mutect2
- CUL9 | c.6241G>A p.D2081N | Missense Mutation (SNP) | VAF 35/385 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as rs763804282, COSV52734634; called by muse, mutect2
- CYP4F11 | c.1187C>T p.P396L | Missense Mutation (SNP) | VAF 45/378 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.009); catalogued as rs141887211; called by muse, mutect2, varscan2
- DEPDC5 | c.2834C>T p.T945M (on ENST00000400246; = p.T1014M on NM_014662.5) | Missense Mutation (SNP) | VAF 47/435 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.459); catalogued as rs780752142; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH2 | c.5575C>T p.R1859C | Missense Mutation (SNP) | VAF 38/410 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201887768; called by muse, mutect2
- DPP10 | c.2266G>T p.D756Y | Missense Mutation (SNP) | VAF 28/276 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59684157; called by muse, mutect2
- DPP8 | c.1477C>T p.R493* (on ENST00000341861 / NM_001320875.2; = p.R477* on NM_017743.6) | Nonsense Mutation (SNP) | VAF 30/272 reads (11%) | catalogued as COSV55681982; called by muse, mutect2
- EGFR | c.3203G>A p.R1068Q | Missense Mutation (SNP) | VAF 54/460 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.241); catalogued as rs374501041; called by muse, mutect2
- EMILIN1 | c.47C>T p.T16M | Missense Mutation (SNP) | VAF 34/486 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as rs777527430, COSV66695549; called by muse, mutect2
- ERVV-2 | c.736C>T p.R246W | Missense Mutation (SNP) | VAF 34/546 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1189681335; called by muse, mutect2
- FGFR1 | c.748C>T p.R250W (on ENST00000447712 / NM_023110.3; = p.R248W on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/271 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as CM063987, COSV58331135; called by muse, mutect2
- GABRB3 | c.773C>T p.T258M | Missense Mutation (SNP) | VAF 40/500 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100161964, COSV54652552, COSV54658230; called by muse, mutect2
- GAD2 | c.1018G>A p.V340M | Missense Mutation (SNP) | VAF 38/399 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs757006706; called by muse, mutect2
- GJA10 | c.227G>T p.R76M | Missense Mutation (SNP) | VAF 43/415 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65354763; called by mutect2, varscan2
- GOLGA6L7 | c.1831G>A p.G611R | Missense Mutation (SNP) | VAF 34/291 reads (12%) | SIFT tolerated, low confidence (0.99); catalogued as rs1166644750; called by muse, mutect2, varscan2
- GREB1L | c.4015C>T p.R1339C | Missense Mutation (SNP) | VAF 32/422 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs938091046, COSV52563671; called by muse, mutect2
- GRIA4 | c.2338G>A p.V780I | Missense Mutation (SNP) | VAF 22/312 reads (7%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as rs761018528, COSV56881287; called by muse, mutect2
- HAPLN4 | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 28/546 reads (5%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as rs1163520328, COSV52271582; called by muse, mutect2
- IGHV3-33 | c.148A>G p.S50G | Missense Mutation (SNP) | VAF 52/724 reads (7%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as rs774237271; called by muse, mutect2
- IGSF22 | c.2215C>T p.R739* (on ENST00000319338; = p.R840* on NM_173588.4) | Nonsense Mutation (SNP) | VAF 37/433 reads (9%) | catalogued as rs531575688, COSV60038196; called by muse, mutect2
- INKA2 | c.647G>A p.R216H | Missense Mutation (SNP) | VAF 37/485 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs139428718, COSV61877241; called by muse, mutect2
- ITIH5 | c.1529C>T p.S510L | Missense Mutation (SNP) | VAF 41/470 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767067116, COSV53667736; called by muse, mutect2
- ITSN1 | c.4763G>A p.R1588H | Missense Mutation (SNP) | VAF 27/346 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs1164637837; called by muse, mutect2
- KCNA4 | c.1348C>T p.R450* | Nonsense Mutation (SNP) | VAF 50/565 reads (9%) | catalogued as COSV60252161; called by muse, mutect2
- KIF23 | c.2735C>T p.S912F (on ENST00000260363; = p.S808F on NM_004856.7) | Missense Mutation (SNP) | VAF 35/415 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as rs1483694119; called by muse, mutect2
- KNDC1 | c.670G>A p.A224T | Missense Mutation (SNP) | VAF 38/438 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs755472769, COSV100464116; called by muse, mutect2
- KRTAP19-7 | c.97C>T p.R33C | Missense Mutation (SNP) | VAF 52/418 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs770876257, COSV58365866; called by muse, mutect2, varscan2
- LIN28B | c.592G>A p.G198R | Missense Mutation (SNP) | VAF 41/367 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.163); catalogued as rs1175916919; called by muse, varscan2
- LPA | c.5072C>T p.T1691M | Missense Mutation (SNP) | VAF 32/383 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.189); catalogued as rs757188741, COSV60314570; called by muse, mutect2
- LRFN1 | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 74/467 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs1291051423; called by muse, mutect2, varscan2
- MYBL2 | c.630C>A p.D210E | Missense Mutation (SNP) | VAF 36/422 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53834103; called by muse, mutect2
- NEXMIF | c.4405C>T p.R1469* | Nonsense Mutation (SNP) | VAF 40/216 reads (19%) | catalogued as rs763067676, COSV50044886; called by muse, mutect2, varscan2
- NKX6-2 | c.338G>A p.R113H | Missense Mutation (SNP) | VAF 48/484 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.14); catalogued as rs1255183154; called by muse, mutect2
- NUP98 | c.4227G>T p.Q1409H (on ENST00000359171 / NM_001365126.1; = p.Q1392H on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/301 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.019); catalogued as rs776133474; called by muse, mutect2
- OR2T12 | c.914C>T p.T305M | Missense Mutation (SNP) | VAF 26/314 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.136); catalogued as rs375506459; called by muse, mutect2
- OVCH1 | c.1789G>A p.D597N | Missense Mutation (SNP) | VAF 34/466 reads (7%) | SIFT tolerated (0.68); PolyPhen benign (0.023); catalogued as rs768253853, COSV58963597; called by muse, mutect2
- PAM | c.2039C>T p.P680L | Missense Mutation (SNP) | VAF 65/341 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.756); catalogued as COSV57211169; called by muse, mutect2, varscan2
- PCDHB14 | c.1849G>A p.V617M | Missense Mutation (SNP) | VAF 89/520 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.929); catalogued as rs199917826; called by muse, mutect2, varscan2
- PCDHB9 | c.970G>A p.G324S | Missense Mutation (SNP) | VAF 52/306 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.22); catalogued as rs1442477881; called by muse, mutect2, varscan2
- POP1 | c.2059C>T p.R687C | Missense Mutation (SNP) | VAF 17/214 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs142902409; called by muse, mutect2
- PPP1R3A | c.1004C>T p.S335F | Missense Mutation (SNP) | VAF 33/345 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs775655362; called by muse, mutect2
- PROX1 | c.842C>A p.S281* | Nonsense Mutation (SNP) | VAF 35/402 reads (9%) | catalogued as COSV54777086, COSV54782718; called by muse, mutect2
- PTPRF | c.1252C>T p.R418C | Missense Mutation (SNP) | VAF 63/561 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as rs759136731, COSV100740882; called by muse, mutect2, varscan2
- RBSN | c.1640G>A p.R547Q | Missense Mutation (SNP) | VAF 51/424 reads (12%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as rs780245188, COSV53795950; called by muse, mutect2, varscan2
- RORC | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 44/449 reads (10%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs199657854, COSV100562254; called by muse, mutect2, varscan2
- SBNO2 | c.2302G>A p.E768K | Missense Mutation (SNP) | VAF 30/460 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as rs758776122; called by muse, mutect2
- SIGLEC8 | c.890G>A p.R297Q | Missense Mutation (SNP) | VAF 56/458 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.094); catalogued as rs779316421, COSV58473308; called by muse, mutect2, varscan2
- SLC41A1 | c.1297G>A p.G433R | Missense Mutation (SNP) | VAF 41/482 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs771501446, COSV100900520, COSV65651163; called by muse, mutect2
- SNX20 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 40/552 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56057901; called by muse, mutect2
- SORCS1 | c.2638G>A p.A880T | Missense Mutation (SNP) | VAF 31/420 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.392); catalogued as rs200375086; called by muse, mutect2
- SRRM4 | c.620G>A p.R207H | Missense Mutation (SNP) | VAF 31/278 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.838); catalogued as rs532719039, COSV57423555; called by muse, mutect2, varscan2
- TBC1D3B | c.490G>A p.G164R | Missense Mutation (SNP) | VAF 12/296 reads (4%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.933); catalogued as rs766187386; called by muse, mutect2
- TGM5 | c.59G>A p.R20Q | Missense Mutation (SNP) | VAF 32/490 reads (7%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs750713894, COSV55009840, COSV55012632; called by muse, mutect2
- TLR9 | c.2695C>T p.R899C | Missense Mutation (SNP) | VAF 37/446 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs781058107, COSV62345676; called by muse, mutect2
- TMEM38A | c.430G>A p.G144R | Missense Mutation (SNP) | VAF 73/386 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775350605; called by muse, mutect2, varscan2
- UBE4B | c.3679G>A p.D1227N (on ENST00000343090 / NM_001105562.3; = p.D1098N on NM_006048.5) | Missense Mutation (SNP) | VAF 26/299 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1020916816; called by muse, mutect2
- ZFAT | c.2288C>T p.T763I | Missense Mutation (SNP) | VAF 24/417 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs78880232, COSV64744270; called by muse, mutect2
- ZNF407 | c.6337G>A p.V2113I | Missense Mutation (SNP) | VAF 48/521 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.118); catalogued as rs776089881, COSV55252837; called by muse, mutect2
- AFF2 | c.1388A>C p.N463T | Missense Mutation (SNP) | VAF 35/157 reads (22%) | SIFT tolerated (0.84); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- APOO | c.561+1G>A p.X187_splice | Splice Site (SNP) | VAF 28/151 reads (19%) | called by muse, mutect2, varscan2
- AXIN2 | c.1431C>A p.Y477* | Nonsense Mutation (SNP) | VAF 50/507 reads (10%) | called by muse, mutect2, varscan2
- C1QTNF5 | c.188G>T p.G63V | Missense Mutation (SNP) | VAF 36/436 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- CADPS | c.1678C>T p.R560W | Missense Mutation (SNP) | VAF 30/265 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CD19 | c.1429G>T p.D477Y | Missense Mutation (SNP) | VAF 24/408 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CFAP47 | c.6719C>T p.T2240I | Missense Mutation (SNP) | VAF 24/177 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- COL11A1 | c.2423G>T p.G808V | Missense Mutation (SNP) | VAF 43/426 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CTNNA1 | c.2200G>T p.G734* | Nonsense Mutation (SNP) | VAF 37/202 reads (18%) | called by muse, mutect2, varscan2
- DCC | c.3936G>A p.M1312I | Missense Mutation (SNP) | VAF 30/425 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2
- DLC1 | c.1705G>A p.D569N (on ENST00000276297 / NM_001348081.2; = p.D132N on NM_006094.5) | Missense Mutation (SNP) | VAF 46/624 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2
- DNAH9 | c.2578A>T p.I860F | Missense Mutation (SNP) | VAF 22/280 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.423); called by muse, mutect2
- ERG | c.773C>T p.P258L (on ENST00000398919 / NM_001243428.1; = p.P234L on NM_004449.4) | Missense Mutation (SNP) | VAF 28/378 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2
- ETV1 | c.1395C>A p.C465* | Nonsense Mutation (SNP) | VAF 54/506 reads (11%) | called by muse, mutect2
- HYOU1 | c.1869G>T p.K623N | Missense Mutation (SNP) | VAF 31/505 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.383); called by muse, mutect2
- IQCJ-SCHIP1 | c.803G>A p.R268H (on ENST00000485419 / NM_001197113.1; = p.R192H on NM_014575.3) | Missense Mutation (SNP) | VAF 51/438 reads (12%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- MIDEAS | c.1543C>T p.R515* | Nonsense Mutation (SNP) | VAF 52/532 reads (10%) | called by muse, mutect2
- NOVA1 | c.371C>G p.P124R | Missense Mutation (SNP) | VAF 30/506 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- NPHS2 | c.628G>A p.V210I | Missense Mutation (SNP) | VAF 40/502 reads (8%) | SIFT tolerated (0.56); PolyPhen benign (0.034); called by muse, mutect2
- OSBP2 | c.2462G>A p.R821H | Missense Mutation (SNP) | VAF 45/409 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHB1 | c.832A>G p.T278A | Missense Mutation (SNP) | VAF 72/439 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- PEG3 | c.1786C>A p.H596N | Missense Mutation (SNP) | VAF 42/592 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2
- PRKN | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 37/356 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- RBMXL2 | c.877G>A p.A293T | Missense Mutation (SNP) | VAF 38/458 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2
- SOX9 | c.1266_1267dup p.F423Sfs*48 | Frame Shift Ins (INS) | VAF 79/452 reads (17%) | called by mutect2, pindel, varscan2
- SYN3 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 33/413 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); called by muse, mutect2
- SYNM | c.792A>G p.I264M | Missense Mutation (SNP) | VAF 24/314 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2
- THSD7A | c.3656G>A p.C1219Y | Missense Mutation (SNP) | VAF 30/319 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- THSD7B | c.1768G>A p.E590K | Missense Mutation (SNP) | VAF 28/372 reads (8%) | SIFT tolerated (0.82); PolyPhen probably damaging (0.999); called by muse, mutect2
- TMEM98 | c.82A>G p.R28G | Missense Mutation (SNP) | VAF 46/340 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- UBN2 | c.1611A>C p.R537S | Missense Mutation (SNP) | VAF 21/307 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); called by muse, mutect2
- UNC80 | c.9516G>T p.E3172D | Missense Mutation (SNP) | VAF 21/268 reads (8%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.953); called by muse, mutect2
- ZNF652 | c.1249del p.W417Gfs*8 | Frame Shift Del (DEL) | VAF 41/402 reads (10%) | called by mutect2, pindel, varscan2
- ACSL5 | c.1419C>T p.Y473= (on ENST00000354273; = p.Y529= on NM_016234.3) | Silent (SNP) | VAF 32/471 reads (7%) | catalogued as rs548491242, COSV61129716; called by muse, mutect2
- AMPD2 | c.1674G>A p.P558= | Silent (SNP) | VAF 23/333 reads (7%) | catalogued as rs1436303547; called by muse, mutect2
- CIT | c.4254C>T p.A1418= | Silent (SNP) | VAF 33/460 reads (7%) | catalogued as rs779999402; called by muse, mutect2
- CLEC16A | c.2295C>T p.D765= | Silent (SNP) | VAF 32/411 reads (8%) | catalogued as rs145100064, COSV55490374; called by muse, mutect2
- COL4A3 | c.3498C>T p.A1166= | Silent (SNP) | VAF 24/342 reads (7%) | catalogued as rs754567461; called by muse, mutect2
- CPA1 | c.945C>A p.P315= | Silent (SNP) | VAF 22/342 reads (6%) | called by muse, mutect2
- DCC | c.3294G>T p.L1098= | Silent (SNP) | VAF 46/520 reads (9%) | catalogued as rs1336185797; called by muse, mutect2
- EDNRB | c.552C>T p.I184= (on ENST00000377211 / NM_001201397.1; = p.I94= on NM_000115.5) | Silent (SNP) | VAF 48/432 reads (11%) | catalogued as COSV57520782; called by muse, mutect2, varscan2
- EEF2 | c.2211G>A p.Q737= | Silent (SNP) | VAF 52/395 reads (13%) | catalogued as rs1222497423; called by muse, mutect2, varscan2
- ELFN2 | c.1992C>T p.I664= | Silent (SNP) | VAF 34/498 reads (7%) | catalogued as rs368780357; called by muse, mutect2
- FAM71B | c.1143G>A p.T381= | Silent (SNP) | VAF 92/424 reads (22%) | catalogued as rs1361578488, COSV57230725; called by muse, mutect2, varscan2
- FBLN2 | c.66C>T p.P22= | Silent (SNP) | VAF 60/642 reads (9%) | called by muse, mutect2
- FECH | c.675C>T p.D225= | Silent (SNP) | VAF 42/324 reads (13%) | catalogued as rs1442450727; called by muse, mutect2, varscan2
- GRM6 | c.1389C>T p.N463= | Silent (SNP) | VAF 36/307 reads (12%) | catalogued as rs139745015; called by muse, mutect2, varscan2
- H4C5 | c.177G>T p.L59= | Silent (SNP) | VAF 34/448 reads (8%) | catalogued as COSV63486833; called by muse, mutect2
- IGFN1 | c.327C>T p.Y109= | Silent (SNP) | VAF 34/430 reads (8%) | catalogued as rs370452044, COSV55182027; called by muse, mutect2
- LRP1B | c.5613T>C p.R1871= | Silent (SNP) | VAF 13/230 reads (6%) | catalogued as rs1422795284, COSV101259661; called by muse, mutect2
- MFSD4A | c.405G>A p.Q135= | Silent (SNP) | VAF 26/348 reads (7%) | called by muse, mutect2
- PCDHB6 | c.816G>A p.S272= | Silent (SNP) | VAF 50/383 reads (13%) | catalogued as rs1463000183, COSV50693020, COSV50728335; called by muse, mutect2, varscan2
- PIK3R5 | c.1602G>A p.A534= | Silent (SNP) | VAF 23/276 reads (8%) | catalogued as rs200430963; called by muse, mutect2
- PRSS53 | c.702C>T p.D234= | Silent (SNP) | VAF 32/405 reads (8%) | catalogued as rs753877424; called by muse, mutect2
- RAB11FIP4 | c.120C>T p.R40= | Silent (SNP) | VAF 25/368 reads (7%) | catalogued as rs776402383; called by muse, mutect2
- RASAL3 | c.567A>G p.E189= | Silent (SNP) | VAF 49/508 reads (10%) | called by muse, mutect2
- SIGLEC9 | c.45G>A p.A15= | Silent (SNP) | VAF 35/331 reads (11%) | catalogued as rs370912487; called by muse, mutect2, varscan2
- SLC25A53 | c.375C>T p.G125= | Silent (SNP) | VAF 46/270 reads (17%) | catalogued as rs782679427; called by muse, mutect2, varscan2
- SOGA3 | c.978G>A p.A326= | Silent (SNP) | VAF 60/585 reads (10%) | catalogued as rs1224402962; called by muse, mutect2
- TBX4 | c.915C>T p.H305= | Silent (SNP) | VAF 61/528 reads (12%) | catalogued as rs148616062; called by muse, mutect2, varscan2
- TDRD7 | c.2682C>T p.S894= | Silent (SNP) | VAF 32/526 reads (6%) | catalogued as rs138199272; called by muse, mutect2
- TECTA | c.1833C>T p.P611= | Silent (SNP) | VAF 47/459 reads (10%) | catalogued as rs767206817, COSV50730702; called by muse, mutect2, varscan2
- TMEM63C | c.1422C>A p.S474= | Silent (SNP) | VAF 36/414 reads (9%) | catalogued as COSV53602783; called by muse, mutect2
- ZNF329 | c.954C>T p.N318= | Silent (SNP) | VAF 40/507 reads (8%) | catalogued as rs1381766156, COSV63772601; called by muse, mutect2
- ZNF585A | c.630A>G p.G210= (on ENST00000292841 / NM_001288800.2; = p.G155= on NM_152655.3) | Silent (SNP) | VAF 30/434 reads (7%) | called by muse, mutect2
- ZPR1 | c.363C>T p.D121= | Silent (SNP) | VAF 14/294 reads (5%) | called by muse, mutect2
- CACNA2D2 | chr3:50363182 C>T | 3'Flank (SNP) | VAF 43/464 reads (9%) | catalogued as rs141530297, COSV99806581; called by muse, mutect2
- GCNT2 | c.925+26603C>T | Intron (SNP) | VAF 22/231 reads (10%) | catalogued as rs747629933, COSV60234482; called by muse, mutect2
- KCNQ1 | c.1394-32239G>T | Intron (SNP) | VAF 34/283 reads (12%) | catalogued as rs1439054436; called by mutect2, varscan2
- KCNQ1 | c.1514+12917C>T | Intron (SNP) | VAF 25/243 reads (10%) | catalogued as rs963200899; called by muse, mutect2, varscan2
- PDGFD | c.125-36669G>A | Intron (SNP) | VAF 43/400 reads (11%) | catalogued as rs781498269, COSV56375420; called by muse, mutect2, varscan2
- ZNF385B | c.298+23773G>A | Intron (SNP) | VAF 29/332 reads (9%) | catalogued as rs762218672; called by muse, mutect2
